Somatic mutation profile of tumor specimen TARGET-50-PAJNUP-01A (aliquot TARGET-50-PAJNUP-01A-01D) from TARGET case TARGET-50-PAJNUP, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.0 years (2,201 days).
Specimen TARGET-50-PAJNUP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f78a18d-93c3-4dbc-9690-78c0b82f8d13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNUP-10A (Blood Derived Normal), aliquot TARGET-50-PAJNUP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cf348f9-04e7-4226-9f08-23ef19725ea7

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 32/38 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASPM | c.4288A>G p.M1430V | Missense Mutation (SNP) | VAF 151/311 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV54130311; called by muse, mutect2, varscan2
- H4C12 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62743844; called by muse, mutect2, varscan2
- MAP3K15 | c.3802C>A p.L1268I | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58830560; called by muse, mutect2, varscan2
- SON | c.5762G>A p.R1921Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.137); catalogued as rs774404358; called by muse, mutect2, varscan2
- TENM1 | c.3647T>C p.V1216A | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV64432570; called by muse, mutect2, varscan2
- ADAMDEC1 | c.518T>C p.F173S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2
- GPATCH2L | c.1273T>C p.S425P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.972); called by muse, mutect2
- SWAP70 | c.1353C>T p.A451= | Splice Region (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- SRPK1 | c.534A>G p.K178= | Silent (SNP) | VAF 11/230 reads (5%) | called by muse, mutect2
